Gene-level copy-number profile of tumor specimen ALCH-B1TZ-TTP1-A from ALCHEMIST case ALCH-B1TZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 83.3 years (30,432 days).
Specimen ALCH-B1TZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3e0dbe02-ffd8-453a-adff-e1da74054a51.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1TZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/013ae501-3286-4796-a5fa-63c326b42567

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 963; copy number 2: 56,974; copy number 3: 365; copy number 4: 21; copy number 5: 7; copy number 6: 8; copy number 8: 6; copy number 11: 1; copy number 15: 2; copy number 17: 1; copy number 22: 1; copy number 28: 2.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–2): PRAMEF29P.
- chr1:13,222,705–13,226,106, 1 gene: PRAMEF18.
- chr1:25,125,053–25,125,454, 1 gene: IFITM3P7.
- chr1:47,333,797–47,378,839, 1 gene: CMPK1.
- chr1:182,054,570–182,090,112, 3 genes: ZNF648, AL355482.1, AL355482.2.
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–2): IGKV2D-14.
- chr2:131,491,160–131,521,573, 2 genes (within-gene range 0–2): MIR4784, SMPD4BP.
- chr2:239,943,015–239,943,094, 1 gene (within-gene range 0–2): MIR4786.
- chr3:46,694,528–46,710,886, 1 gene: TMIE.
- chr3:46,719,583–46,736,429, 1 gene (within-gene range 0–2): PRSS46P.
- chr4:9,493,736–9,498,066, 1 gene: UNC93B7.
- chr4:118,591,773–118,638,782, 3 genes: AC110079.1, RNU6-1054P, CICP16.
- chr5:80,288,449–80,289,781, 1 gene: KRT18P45.
- chr6:34,715,613–34,715,940, 1 gene: AL451165.1.
- chr9:129,883,693–129,884,170, 1 gene: AL158207.1.
- chr9:133,654,586–133,657,313, 1 gene (within-gene range 0–2): DBH-AS1.
- chr11:71,473,503–71,473,568, 1 gene (within-gene range 0–2): MIR6754.
- chr12:57,819,927–57,846,729, 3 genes (within-gene range 0–2): CTDSP2, MIR26A2, AC083805.2.
- chr13:19,152,567–19,181,824, 3 genes: SMPD4P2, AL139327.3, TUBA3C.
- chr14:100,109,419–100,159,645, 3 genes (within-gene range 0–2): MIR151B, MIR342, DEGS2.
- chr14:105,486,317–105,499,575, 3 genes: CRIP1, AL928654.3, TEDC1.
- chr16:57,610,652–57,665,580, 2 genes (within-gene range 0–2): ADGRG1, AC018552.3.
- chr16:89,873,570–89,913,627, 1 gene (within-gene range 0–2): TCF25.
- chr17:9,171,068–9,179,118, 1 gene (within-gene range 0–2): AC005695.1.
- chr17:19,719,059–19,722,428, 1 gene: AC005722.3.
- chr18:79,352,458–79,354,567, 1 gene (within-gene range 0–2): AC023090.2.
- chr22:21,207,973–21,227,637, 1 gene (within-gene range 0–5): GGT2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,632,568–2,636,620, 1 gene, copy number 6 (within-gene range 2–6): MMEL1-AS1.
- chr9:136,658,856–136,672,678, 2 genes, copy number 5 (within-gene range 3–5): EGFL7, MIR126.
- chr11:67,491,768–67,508,649, 2 genes, copy number 8: PITPNM1, CDK2AP2.
- chr16:85,798,633–85,816,536, 3 genes, copy number 6 (within-gene range 2–6): COX4I1, AC018695.5, AC018695.1.
- chr16:90,093,154–90,096,354, 1 gene, copy number 5: TUBB8P7.
- chr21:43,107,942–43,168,646, 1 gene, copy number 28 (within-gene range 2–28): AP001631.2.
- chr21:43,159,066–43,172,805, 2 genes, copy number 11–28: AP001631.1, CRYAA.
- chr21:44,217,014–44,262,216, 5 genes, copy number 6–8: ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.
- chr22:21,103,016–21,203,755, 5 genes, copy number 5–17: BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM247A.
- chr22:21,228,760–21,268,903, 2 genes, copy number 5 (within-gene range 5–7): AP000550.3, E2F6P3.
- chr22:21,341,595–21,358,067, 2 genes, copy number 15: PPP1R26P5, LINC01651.
- chr22:21,379,382–21,396,590, 2 genes, copy number 8–22: Metazoa_SRP, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 963. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
